Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1Y0, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1Y0-01A (Primary Tumor).

[page 1 of 2]
Department of Cancer Pathology

copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: Total organ resection - left breast and axillary tissues

Unit in charge: (

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: up to 8 working days

Clinical diagnosis:

ICD-0-3

carcinoma, infiltrating duct, nos 8500/3

Site: breast, nos C50.9 in 4/12/11

Examination performed on:

Macroscopic description:

Left breast sized 24 x 19.5 x 5 cm removed with axillary tissues sized 10 x 7 x 2.5 cm and a skin flap of 24 x 12 cm. Tumour sized 1.9 x 1.3 x 1.4 found in the subareolar part, located 5.2 cm from the upper boundary, 2.8 cm from the base and 0 cm from the skin. Metastatic lymph nodes 2 cm in length.

Microscopic description:

Carcinoma ductale invasivum - NHG2 (3 + 2 + 1 / 6 mitoses/10 HPF - visual area 0.55 mm).

Foci of carcinoma ductale in situ DCIS detected within the tumour (cribrate and solid type with high nuclear atypia with comedo necrosis, 5% of the tumour).

Mamilla sine laesionibus. Glandular tissue showing lesions of the type mastopathia fibrosa.

AXILLARY LYMPH NODES

Metastases carcinomatosae in lymphonodis (No IX/XV). Infiltratio capsulae lymphonodis et telae perinodalis.

Histopathological diagnosis:

Carcinoma ductale invasivum et ductale in situ mammae sinistrae. Invasive ductal and in situ ductal carcinoma of the left breast.

Metastases carcinomatosae in lymphonodis axillae (No IX/XV). Cancer metastases of the axillary lymph nodes (No IX/XV). (NHG2, pT1c, pN2a).

Diagnostic Discrepancy		☒

[page 2 of 2]
Compliance validated by:
Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei. Progesterone receptors found in over 75% of neoplastic cell nuclei.

HER2 protein stained with HercepTest™ by DAKO.

Negative reaction in invasive cancerous cells (Score = 1+)

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 0010ce59-fd1e-4a45-8753-a224164fb818 (TCGA-D8-A1Y0.53ED4388-8CD2-4925-81A9-9C4792C83566.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).